Somatic mutation profile of tumor specimen 0DWES5 from CCDI case PBCMSM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,589 days).
Specimen 0DWES5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eb321af-8a59-43f4-8d36-c77ea367c53a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWERW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1097df1-4439-45f5-81b8-28589ae1cf66

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC17 | c.13450C>A p.Q4484K | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV60287905; called by muse, varscan2
- FAM47C | c.519C>T p.D173= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100792325; called by muse, mutect2, varscan2
